Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7399, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7399-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

- 1) LARYNX, BIOPSY: POORLY DIFFERENTIATED CARCINOMA.
- 2) LARYNX, LEFT HYPOPHARYNX MARGIN, LARYNGECTOMY: NEGATIVE FOR MALIGNANCY.
- 3) LARYNX, LEFT OROPHARYNX MARGIN, LARYNGECTOMY: NEGATIVE FOR MALIGNANCY.
- 4) LARYNX, LEFT BASE OF TONGUE MARGIN, LARYNGECTOMY: NEGATIVE FOR MALIGNANCY.
- 5) LARYNX, POSTCRICOID MARGIN, LARYNGECTOMY: NEGATIVE FOR MALIGNANCY.
- 6) LARYNX, RIGHT HYPOPHARYNX MARGIN, LARYNGECTOMY: NEGATIVE FOR MALIGNANCY.
- 7) LARYNX, RIGHT OROPHARYNX MARGIN, LARYNGECTOMY: NEGATIVE FOR MALIGNANCY.
- 8) LARYNX, RIGHT BASE OF TONGUE MARGIN, LARYNGECTOMY: NEGATIVE FOR MALIGNANCY.
- 9) LYMPH NODES, LEVEL 1A, EXCISION: 2 LYMPH NODES, NEGATIVE FOR MALIGNANCY.
- 10) LYMPH NODE, LEFT JUGULAR FORAMEN, EXCISION: 1 LYMPH NODE, NEGATIVE FOR MALIGNANCY.
- 11) LYMPH NODES, LEFT LEVEL 2, 3, 4 AND 5, EXCISION: 3 OF 20 LYMPH NODES INVOLVED BY CARCINOMA; LARGEST AT LEVEL ii, 4.8 CM IN GREATEST DIMENSION; NEGATIVE FOR EXTRANODAL EXTENSION.
- 12) LYMPH NODES, LEFT LEVEL 1B, EXCISION: 1 OF 5 LYMPH NODES INVOLVED BY CARCINOMA, 0.6 CM IN GREATEST DIMENSION, NEGATIVE FOR EXTRANODAL EXTENSION; SALIVARY GLAND NEGATIVE FOR MALIGNANCY.
- 13) LYMPH NODES, RIGHT LEVEL 2, 3, 4 AND 5, EXCISION: 2 OF 23 LYMPH NODES INVOLVED BY CARCINOMA; LARGER AT LEVEL III, 4.6 CM IN GREATEST DIMENSION, WITH EXTRANODAL EXTENSION OF TUMOR.
- 14) LYMPH NODES, RIGHT SUPERIOR MEDIASTINUM, EXCISION: 1 LYMPH NODE, NEGATIVE FOR MALIGNANCY.
- 15) LYMPH NODES, RIGHT LEVEL 1B, EXCISION: 5 LYMPH NODES, NEGATIVE FOR MALIGNANCY; SALIVARY GLAND, NEGATIVE FOR MALIGNANCY.
- 16) SOFT TISSUE, RIGHT PERISTOMAL, EXCISION: SKIN AND SKELETAL MUSCLE WITH

[page 2 of 6]
ORGANIZED GRANULATION TISSUE, NEGATIVE FOR MALIGNANCY.

17) LARYNX, LARYNGECTOMY: POORLY DIFFERENTIATED SUPRAGLOTTIC SQUAMOUS CELL CARCINOMA, 2.3 CM IN GREATEST DIMENSION, INVADING PRE-EPIGLOTTIC SPACE; PRESENT 0.1 CM FROM RIGHT MUCOSAL AND SOFT TISSUE RESECTION MARGINS; ALL SURGICAL MARGINS NEGATIVE FOR MALIGNANCY, NEGATIVE FOR EXTENSION INTO VOCAL CORDS OR THYROID CARTILAGE, (SEE COMMENT).

Comment: These findings correspond to AJCC stage IV A (pT3, N2c, Mn/a) disease.

**Electronically Signed Out by [REDACTED] **

[REDACTED]

CLINICAL DATA

Clinical Features: Unspecified

Operator: [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1) Larynx; 2) Left hypopharynx margin; 3)

Left oropharynx margin; 4) Left base of tongue; 5) Postcricoid margin; 6) Right hypopharynx margin; 7) Right oropharynx margin; 8) Right base of tongue; 9) Neck nodes level 1A; 10) Left jugular foramen node; 11) Left neck level 2, 3, 4, 5; 12) Left neck level 1B; 13) Right neck level 2, 3, 4, 5; 14) Right superior mediastinal lymph node; 15) Right neck dissection level 1B; 16) Right peristomal tissue; 17) Laryngeal cancer

GROSS DESCRIPTION:

1) SOURCE: Larynx

Received fresh are two fragments of tan soft tissue measuring 1.0 x 0.4 x 0.4 cm. The specimens are submitted in their entirety for frozen-section analysis.

Summary of sections: 1AFSC, 2/1.

2) SOURCE: Left Hypopharynx Margin

Received fresh is a 2.9 x 0.2 x 0.2 cm strip of mucosa. The specimen is inked black and submitted in its entirety for frozen-section analysis.

Summary of sections: 2AFSC, 1/1.

3) SOURCE: Left Oropharynx Margin

Received fresh is a 3.7 x 0.2 x 0.2 cm fragment of pink-tan mucosa. The

[REDACTED]

[page 3 of 6]
specimen is submitted in its entirety for frozen-section analysis.
Summary of sections: 3FSC, 1/1.

4) SOURCE: Left Base of Tongue

Received fresh is a 2.8 x 0.4 x 0.3 cm fragment of pink-tan mucosa. The specimen is inked black and submitted in its entirety for frozen-section analysis.
Summary of sections: 4FSC, 1/1.

5) SOURCE: Postcricoid Margin

Received fresh is a 3.2 x 0.2 x 0.2 cm fragment of pink-tan mucosa. The specimen is submitted in its entirety for frozen-section analysis.
Summary of sections: 5AFSC, 1/1.

6) SOURCE: Right Hypopharynx

Received fresh is a 4.5 x 0.2 x 0.2 cm fragment of pink-tan mucosa. The specimen is inked black and submitted in its entirety for frozen-section analysis.
Summary of sections: 6AFSC, 1/1.

7) SOURCE: Right Oropharynx

Received fresh is a 4.6 x 0.2 x 0.2 cm fragment of pink-tan mucosa. The specimen is submitted in its entirety for frozen-section analysis.
Summary of sections: 7AFSC, 1/1.

8) SOURCE: Right Base of Tongue

Received fresh is a 4.9 x 0.2 x 0.2 cm fragment of pink-tan soft tissue. The specimen is submitted in its entirety for frozen-section analysis.
Summary of sections: 8AFSC, 1/1.

9) SOURCE: Neck Nodes Level 1A

Received fresh is as single portion of yellow-pink adipose tissue measuring 3.7 x 3.5 x 0.8 cm. The specimen is submitted in its entirety.
Summary of sections: 9A, 9B, 2/1 each; 9C, 1/1.

10) SOURCE: Left Jugular Foramen Node

Received fresh is a single pink-tan lymph node measuring 1.3 x 0.6 x 0.4 cm. The specimen is submitted in its entirety.
Summary of sections: 10A, 1/1.

11) SOURCE: Left Neck Level 2,3,4,5

Received fresh is a single complicated specimen consisting of soft tissue and embedded lymph nodes measuring 14.0 x 6.0 x 2.8 cm. A thorough search is made for the lymph nodes and all lymph node candidates identified are submitted. The largest node that is present measures 4.8 x 2.8 x 2.2 cm and is firm and white on its external surface. Serial sectioning reveals

[page 4 of 6]
homogeneous white firm tan interior. In the level 3 area is a single white, firm, nodular mass measuring 4.2 x 1.8 x 1.5 cm. Cross sectioning of this specimen reveals homogeneous white firm interior.

Summary of sections: 11A, large level 2 /lymph node, 1/1; 11B-11D, additional tissue from level 2, M/1 each; 11E, large level 3 lymph node, two slices, 2/1; 11F, 11G, additional level 3 lymph node candidates, M/1 each; 11H, level 4 lymph node candidates, M/1; 11I, level 5 lymph node candidates, M/1.

12) SOURCE: Left Neck Level IB

Received fresh is a large portion of brown-tan salivary tissue and adherent yellow soft tissue and lymph nodes measuring 6.5 x 4.0 x 2.0 cm. A thorough search of the specimen is made of the lymph nodes. All lymph node candidates identified are submitted in their entirety.

Summary of sections: 12A, lymph node candidates, 3/1; 12B, lymph node candidates, 2/1; 12C, section of salivary gland, 1/1.

13) SOURCE: Right Neck Level 2,3,4,5

Received fresh is a complicated neck section specimen with portion of the jugular vein and sternocleidomastoid muscle measuring 13.0 x 5.5 x 3.0 cm. The specimen is grossly remarkable for several large white firm nodes with homogeneous white cut surfaces. One at level 3 measures 4.6 x 2.0 x 1.8 cm.

Another at level 4 measures 3.4 x 2.0 x 1.8 cm. Representative sections of these are submitted, along with all other lymph node candidates identified. Summary of sections: 13A-13D, level 2 candidate lymph nodes, M/1 each; 13; 13E, level 3 large involved lymph node, 1/1; 13F, level 4 large involved lymph node, 1/1; 13G, additional level 4 lymph node candidates, 4/1; 13H-13K, level 5 lymph node candidates, M/1 each; 13L, a single level 5 lymph node bisected, 1/1.

14) SOURCE: Right Superior Mediastinal Lymph node

Received fresh is a single fragment of yellow-red to black-brown soft tissue measuring 1.8 x 1.0 x 0.8 cm. The specimen is bisected and submitted in its entirety.

Summary of sections: 14A, 2/1.

15) SOURCE: Right Neck Dissection Level IB

Received fresh is a single specimen consisting of brownish-tan salivary gland tissue with attached fragments of yellow-red adipose tissue and lymph nodes. The specimen measures 4.6 x 4.0 x 1.8 cm.

Summary of sections: 15A, single bisected lymph node, 2/1; 15B, multiple candidate lymph nodes, 4/1; 15C, section of salivary gland, 1/1.

16) SOURCE: Right Periostoma Tissue

Received fresh are three fragments of yellow-tan to brown adipose tissue and granulation tissue measuring 5.5 x 4.0 x 1.0 cm. Representative sections are submitted.

Summary of sections: 16A, 16B, 2/1 each.

[page 5 of 6]
17) SOURCE: Laryngeal Cancer

Received fresh is a laryngectomy specimen measuring 8.0 cm from superior to inferior x 6.5 cm transversely x 6.0 cm from anterior to posterior. The laryngectomy portion of the specimen measures 1.9 cm in diameter at the inferior laryngeal margin. The anterior soft tissue portion of the specimen measures 3.5 cm from anterior to posterior x 5.0 cm transversely x 4.5 cm from superior to inferior. The specimen ends at the superior portion in epiglottis and aryepiglottic folds and at the bottom in a round laryngeal tracheal ring. The specimen is inked in the following fashion: superior yellow, inferior green, posterior black, anterior orange, right red and left blue. It is then opened posteriorly revealing a large ulcerated mass lying in the midline on the inferior surface of the epiglottis and extending 2.3 cm in greatest dimension, from superior to inferior. Grossly it lies 0.3 cm away from the vocal folds, 3.2 cm away from the inferior margin, and 0.2 cm away from the aryepiglottic folds and 1.3 cm away from the hypopharyngeal soft tissue margins grossly. The distance to the anterior surface of the soft tissue margins is approximately 2.0 cm. Summary of sections: 17A, inferior tracheal margin, 1/1; 17B, 17C, cross sections of superficial tumor, 1/1 each; 17D, anterior and superior soft tissue margins, 2/1; 17E, right vocal fold and thyroid cartilage, 1/1; 17F, left vocal fold and thyroid cartilage, 1/1; 17G, right mucosal margin, 1/1; 17H, left mucosal margin, 1/1; 17I, right soft tissue margin, 1/1; 17J, left soft tissue margin, 1/1; 17K, epiglottis, 1/1.

Dictated by [REDACTED]

Slides and report reviewed by Attending Pathologist.

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Larynx

FROZEN SECTION DIAGNOSIS: POORLY-DIFFERENTIATED CARCINOMA. [REDACTED]

2) SOURCE: Left Hypopharynx Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

3) SOURCE: Left Oropharynx Margin

FROZEN SECTION DIAGNOSIS: BENIGN [REDACTED]

4) SOURCE: Left Base of Tongue

FROZEN SECTION DIAGNOSIS: BENIGN [REDACTED]

5) SOURCE: Post-Cricoid Margin

FROZEN SECTION DIAGNOSIS: BENIGN [REDACTED]

6) SOURCE: Right Hypopharynx

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

[REDACTED]

[page 6 of 6]
7) SOURCE: Right Oropharynx

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

8) SOURCE: Right Base of Tongue

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]—

Electronically signed by: [REDACTED] Attending Pathologist

Source: NCI Genomic Data Commons file 139fa763-4233-498f-90fb-7265c3de8274 (TCGA-CR-7399.236C8A47-392C-4980-9C1F-25997CECAAF1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).